CCDI case PBCCTL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f297f670-9adf-45ba-b90b-5e19231e97a2

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,880 days).

Biospecimens (3 samples)
- Sample 0E1CVU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1CWN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1CX3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
